Somatic mutation profile of tumor specimen TARGET-30-PAMZMG-01A (aliquot TARGET-30-PAMZMG-01A-01W) from TARGET case TARGET-30-PAMZMG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.7 years (614 days).
Specimen TARGET-30-PAMZMG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1327f8a-8bc8-4619-abac-ea58730ab75b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMZMG-10A (Blood Derived Normal), aliquot TARGET-30-PAMZMG-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34496fdb-bab0-4441-b086-0455b9e4e514

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 121/527 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs376792697; called by muse, mutect2, varscan2
- CEP290 | c.3922C>A p.Q1308K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as CM071593, COSV58354441; called by muse, mutect2, varscan2
- CHRNA3 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58776544; called by muse, mutect2, varscan2
- GEN1 | c.1538del p.P513Lfs*14 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as COSV58055185; called by mutect2, pindel, varscan2
- LRPAP1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs367608534, COSV99579087; called by muse, mutect2, varscan2
- NKX2-1 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV61389830, COSV61389878; called by muse, mutect2, varscan2
- TAS2R39 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV71470976; called by muse, mutect2, varscan2
- TIA1 | c.1022A>T p.Q341L (on ENST00000433529 / NM_001351511.1; = p.Q330L on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57007458; called by muse, mutect2, varscan2
- COL4A1 | c.1928C>A p.P643H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.871); called by muse, mutect2
- SYMPK | c.1534dup p.L512Pfs*62 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- CRB1 | c.606C>A p.L202= | Silent (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- ITGB4 | c.852C>T p.N284= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs529755730, COSV52330572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC26 | c.1623G>T p.R541= | Silent (SNP) | VAF 58/427 reads (14%) | catalogued as COSV58273532; called by muse, mutect2, varscan2
- MIR512-2 | n.47G>T | RNA (SNP) | VAF 31/68 reads (46%) | called by mutect2, varscan2
